Surgical pathology report (de-identified scan), TCGA case TCGA-P5-A730, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Cureline, specimen TCGA-P5-A730-01A (Primary Tumor).

ICD-O-3
Oligoastrocytoma, grade III
938213
Site: Brain, supratentorial NOS
C71.0
JW 8/15/13

Case #

Patient: Age (years): Gender:

Clinical diagnosis: Brain tumor

Date of procurement:

Sample:

Gross description:

The material presented by grayish soft-elastic pieces of right occipital and parietal lobes

Microscopic description:

Received material is represented by brain tissue consistent with anaplastic oligoastrocytoma.

Final diagnosis: Anaplastic oligoastrocytoma: Grade III

Source: NCI Genomic Data Commons file f80c1aa7-3615-43f8-a6fd-664cd7201948 (TCGA-P5-A730.D03B2072-0B67-431A-9C5E-0D0B4191E846.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).